Gene-level copy-number profile of tumor specimen TCGA-DK-A1AD-01A from TCGA case TCGA-DK-A1AD, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 69.3 years (25,317 days).
Specimen TCGA-DK-A1AD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.a661ee19-9400-4339-ad38-b7c9a3a574f7.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A1AD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 421 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7b50e584-d778-4e80-8973-cfc14b730b92

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 1,552; copy number 2: 17,676; copy number 3: 18,821; copy number 4: 12,739; copy number 5: 6,106; copy number 6: 1,725; copy number 7: 583; copy number 8: 453; copy number 9: 97; copy number 10: 243; copy number 11: 72; copy number 13: 49; copy number 14: 4; copy number 15: 20; copy number 16: 11; copy number 23: 33; copy number 24: 2; copy number 26: 1; copy number 29: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A1AD-01A-11D-A13V-01): tumor purity 0.73, ploidy 3.08, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:212,911,003–212,937,520, 4 genes: AC108066.1, MIR4776-1, MIR4776-2, AC108066.2.
- chr17:18,460,391–18,463,055, 1 gene: TNPO1P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,578 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,614,333–121,580,524, 80 genes, copy number 8 (broad region; genes not listed).
- chr1:152,565,654–152,776,728, 17 genes, copy number 11 (within-gene range 6–11): LCE3E, LCE3D, LCE3C, LCE3B, LCE3A, LCEP4, LCEP3, LCE2D, LCE2C, LCE2B, LCE2A, LCE4A, C1orf68, LCEP2, LCEP1, KPRP, LCE1F.
- chr1:152,878,322–154,220,637, 89 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr1:157,794,403–158,700,652, 34 genes, copy number 9: FCRL1, CD5L, MRPS21P2, AL139010.1, KIRREL1, KIRREL1-IT1, SMIM42, LINC01704, ELL2P1, CD1D, AL138899.2, AL138899.1, CD1A, HMGN1P5, CD1C, CD1B, CD1E, OR10T2, OR10K2, OR10T1P, EI24P2, OR10K1, OR10R2, AL365440.1, OR10R3P, OR10R1P, HSP90AA3P, OR6Y1, OR6P1, OR10X1, OR10Z1, SPTA1, OR6K1P, OR6K2.
- chr1:158,747,814–163,468,605, 186 genes, copy number 7–13 (within-gene range 5–13) (broad region; genes not listed).
- chr2:142,131,178–145,338,057, 41 genes, copy number 7–8: AC078882.1, UBE2V1P14, RRN3P4, KYNU, SFXN4P1, ARHGAP15, MTCYBP11, MTND6P11, MTND5P24, MTND4P22, MTND4LP12, MTND3P9, MTCO3P5, MTATP6P5, MTCO2P5, AC013437.1, AC079793.1, AC092652.2, ARHGAP15-AS1, AC092652.1, AC079584.2, AC079584.1, Y_RNA, AC016910.1, GTDC1, ZEB2, AC009951.5, AC009951.4, ZEB2-AS1, AC009951.2, AC009951.1, AC009951.3, AC009951.6, LINC01412, TEX41, AC023128.1, AC023128.2, SGCEP1, LINC01966, AC096666.1, RPL6P5.
- chr3:175,059,361–175,115,242, 2 genes, copy number 8 (within-gene range 5–8): EEF1B2P8, NAALADL2-AS3.
- chr4:57,720,035–58,103,434, 3 genes, copy number 8: AC093725.1, AC104790.1, SRIP1.
- chr4:68,053,198–68,129,869, 1 gene, copy number 10 (within-gene range 3–10): TMPRSS11F.
- chr4:68,182,292–69,526,014, 56 genes, copy number 10: FTLP10, TMPRSS11BNL, TMPRSS11B, AC098799.3, AC098799.1, AC098799.2, APOOP4, YTHDC1, MT2P1, TMPRSS11E, UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15, AC147055.1, AC093720.1, AC021146.8, UGT2B10, AC021146.9, AC021146.4, AC021146.11, AC021146.2, AC021146.3, AC021146.12, AC021146.6, AC021146.1, UGT2A3, AC021146.10, AC021146.5, AC021146.7, UGT2B27P, AC107401.1, UGT2B26P, UGT2B7, AC111000.2, AC111000.5, AC111000.3, AC111000.6, AC111000.1, AC111000.4, UGT2B11, AC114797.1, AC114786.1, UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P, AC108078.3, AC108078.2, UGT2B4, UGT2A3P7.
- chr6:17,953,572–23,649,774, 60 genes, copy number 14–29: AL023807.1, NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1, AL133270.1.
- chr6:32,517,353–32,530,287, 1 gene, copy number 26: HLA-DRB5.
- chr6:63,392,222–71,652,611, 81 genes, copy number 7–15 (broad region; genes not listed).
- chr7:4,130,181–5,233,840, 25 genes, copy number 7: AC017000.1, CYP3A54P, AC072054.1, FOXK1, AC092428.1, AP5Z1, MIR4656, AC092610.1, RADIL, Y_RNA, PAPOLB, RPL22P16, MMD2, RNF216P1, AC092032.2, RBAK-RBAKDN, AC092032.3, AC092032.1, SPDYE19P, RBAK, RBAKDN, OR10AH1P, ZNF890P, RNU6-215P, WIPI2.
- chr7:29,650,227–29,917,066, 4 genes, copy number 9 (within-gene range 6–9): DPY19L2P3, MIR550A3, WIPF3, AC004912.1.
- chr7:33,001,950–33,109,404, 5 genes, copy number 7: RNU6-388P, NT5C3A, RPS29P14, RN7SL505P, RP9.
- chr7:33,128,988–33,177,838, 2 genes, copy number 7: AC074338.1, RNA5SP229.
- chr7:148,963,315–148,989,432, 4 genes, copy number 9: RNY4, RNY3, RNY1, GHET1.
- chr8:41,645,177–43,544,057, 63 genes, copy number 7 (broad region; genes not listed).
- chr10:44,712–18,545,651, 318 genes, copy number 7–8 (broad region; genes not listed).
- chr10:32,446,140–33,336,262, 13 genes, copy number 7 (within-gene range 4–7): CCDC7, C1DP1, ITGB1, AK3P5, ITGB1-DT, MTND4LP11, RN7SL847P, AL365203.1, RPL7AP53, IATPR, NRP1, AL121748.1, RN7SL398P.
- chr10:35,247,025–35,572,669, 1 gene, copy number 8 (within-gene range 6–8): CCNY.
- chr10:35,314,552–35,800,920, 9 genes, copy number 8: AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5.
- chr10:51,062,579–51,320,660, 5 genes, copy number 7: AL731537.1, AC022537.1, MIR605, AC069079.1, RSU1P3.
- chr12:32,000,375–32,007,435, 2 genes, copy number 8: AC016957.2, AC016957.1.
- chr13:37,481,467–38,350,259, 9 genes, copy number 7 (within-gene range 6–7): LINC01048, LINC00547, POSTN, TRPC4, RNA5SP26, AL356495.1, LINC02334, HSPD1P9, LINC00571.
- chr13:41,061,509–41,590,462, 20 genes, copy number 8 (within-gene range 5–8): WBP4, MIR3168, RN7SL597P, KBTBD6, AL354696.2, CALM2P3, KBTBD7, MORF4L1P4, MTRF1, AL354696.1, RAC1P3, NAA16, RNU6-57P, TUBBP2, OR7E36P, OR7E155P, OR7E37P, RGCC, AL354833.2, AL354833.1.
- chr13:41,568,286–41,568,395, 1 gene, copy number 8: MIR5006.
- chr13:44,982,077–45,083,125, 1 gene, copy number 7 (within-gene range 3–7): AL359706.1.
- chr13:45,060,729–45,061,086, 1 gene, copy number 7: RN7SKP3.
- chr19:29,001,670–32,405,560, 57 genes, copy number 7–11 (within-gene range 5–11): RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P, LINC01837, LINC01533, LINC01782, AC011518.1, AC074139.1, RNA5SP472, ZNF507, AC007773.1.
- chr19:37,728,586–40,898,282, 168 genes, copy number 7–10 (broad region; genes not listed).
- chr21:23,352,929–23,890,541, 8 genes, copy number 7–8 (within-gene range 5–8): D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1, AP000961.1, AP000474.2, AP000474.1.
- chr21:30,829,039–39,730,680, 211 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,324. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
